Somatic mutation profile of tumor specimen TARGET-30-PAUBWP-01A (aliquot TARGET-30-PAUBWP-01A-01D) from TARGET case TARGET-30-PAUBWP, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.5 years (926 days).
Specimen TARGET-30-PAUBWP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98580dbc-3571-4584-93c8-efd334e6dfa7.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUBWP-10A (Blood Derived Normal), aliquot TARGET-30-PAUBWP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/640978e1-2ebb-40fd-9295-c1cd2fb5181c

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'Flank 1, Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH2 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV55430984; called by muse, mutect2
- ANKRD28 | c.996C>A p.I332= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV101080789, COSV67519265; called by muse, mutect2, varscan2
- VANGL1 | chr1:115692670 G>A | 3'Flank (SNP) | VAF 39/163 reads (24%) | catalogued as COSV59621303; called by muse, mutect2, varscan2
